Somatic mutation profile of tumor specimen TCGA-49-4501-01A (aliquot TCGA-49-4501-01A-01D-1265-08) from TCGA case TCGA-49-4501, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 67.9 years (24,817 days).
Specimen TCGA-49-4501-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b342cdbc-5af1-4ed9-baf3-d7c129ee75a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-4501-11A (Solid Tissue Normal), aliquot TCGA-49-4501-11A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e07a5517-ab7e-4367-971b-7719c3273a1c

The open-access MAF lists 50 somatic variants for this specimen: 33 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 16, In Frame Del 2, Splice Site 2, Nonsense Mutation 1, In Frame Ins 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 27/142 reads (19%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- ADAMTS9 | c.4091A>G p.N1364S | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55777876; called by muse, mutect2
- AKAP12 | c.2495G>C p.G832A | Missense Mutation (SNP) | VAF 58/286 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); catalogued as COSV53572605; called by muse, mutect2, varscan2
- CARD11 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62716778, COSV62717018; called by muse, mutect2
- CENPE | c.7287T>A p.N2429K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV54378861, COSV99479465; called by muse, mutect2, varscan2
- CIT | c.5869C>T p.H1957Y | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV55864620; called by muse, mutect2, varscan2
- CYP2F1 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as rs746849388, COSV58527059; called by muse, mutect2, varscan2
- DAPK2 | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 88/259 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56044602; called by muse, mutect2, varscan2
- DCTN1 | c.2231T>C p.M744T | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV62620051; called by muse, mutect2, varscan2
- DNAH1 | c.11162T>C p.I3721T | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1201041664, COSV70227593; called by muse, mutect2, varscan2
- ENPP1 | c.2213G>A p.G738E | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as COSV62931325; called by muse, mutect2, varscan2
- ERICH3 | c.2782T>A p.S928T | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV58603111; called by muse, mutect2
- FAM71B | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.263); catalogued as COSV57228266; called by muse, mutect2
- GPBP1L1 | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.623); catalogued as COSV51968243; called by muse, mutect2, varscan2
- HOXA9 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754844230, COSV58655962; called by muse, mutect2, varscan2
- MAGED1 | c.2321T>A p.F774Y | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.441); catalogued as COSV58514881; called by muse, mutect2
- MAP7D2 | c.1639A>C p.I547L | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65526405; called by muse, mutect2
- NUDT2 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs1312609869, COSV60678621; called by muse, mutect2, varscan2
- NUP58 | c.1405A>G p.T469A | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as rs767482542, COSV67751118; called by muse, mutect2
- OR1J2 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV58944089; called by muse, mutect2, varscan2
- PCDHA1 | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as COSV65373454; called by muse, mutect2, varscan2
- PRKN | c.1285+1G>T p.X429_splice | Splice Site (SNP) | VAF 34/339 reads (10%) | catalogued as COSV58213672; called by muse, mutect2, varscan2
- PTPRJ | c.3499G>T p.A1167S | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as COSV69250956; called by muse, mutect2, varscan2
- SCAI | c.1065+1G>T p.X355_splice (on ENST00000336505 / NM_001144877.3; = p.X378_splice on NM_173690.5) | Splice Site (SNP) | VAF 46/257 reads (18%) | catalogued as COSV60611408; called by muse, mutect2, varscan2
- SPEN | c.7547C>T p.P2516L | Missense Mutation (SNP) | VAF 83/403 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.922); catalogued as rs778553422, COSV65359836; called by muse, mutect2, varscan2
- TPCN1 | c.1994G>A p.R665H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1367837135, COSV59233941; called by muse, mutect2, varscan2
- USP15 | c.1760C>A p.S587* (on ENST00000280377 / NM_001351159.2; = p.S558* on NM_006313.3 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 9/90 reads (10%) | catalogued as COSV54788596; called by muse, mutect2
- ZDHHC16 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs749099703, COSV61748942; called by muse, mutect2, varscan2
- ZDHHC5 | c.124T>A p.Y42N | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV54705945; called by muse, mutect2, varscan2
- ZSWIM2 | c.739T>C p.Y247H | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54574595; called by muse, mutect2
- MAN1A2 | c.494_514del p.V165_P172delinsA | In Frame Del (DEL) | VAF 12/59 reads (20%) | called by mutect2, pindel, varscan2
- PRR12 | c.3493_3494insT p.R1165Lfs*35 (on ENST00000615927; = p.R1986Lfs*35 on NM_020719.3) | Frame Shift Ins (INS) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- TOP3A | c.1314_1316dup p.R439dup | In Frame Ins (INS) | VAF 18/81 reads (22%) | called by mutect2, pindel, varscan2
- ATRX | c.783C>T p.N261= | Silent (SNP) | VAF 28/290 reads (10%) | catalogued as COSV64873990; called by muse, mutect2
- CAPN11 | c.1185C>T p.Y395= | Silent (SNP) | VAF 26/224 reads (12%) | catalogued as rs775516151, COSV67236913; called by muse, mutect2, varscan2
- ELP1 | c.1593G>A p.L531= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as rs773965613, COSV65897040; called by muse, mutect2, varscan2
- JAKMIP2 | c.2391A>G p.Q797= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV54600998, COSV54609612; called by muse, mutect2
- KL | c.1444C>T p.L482= | Silent (SNP) | VAF 10/233 reads (4%) | catalogued as COSV66308326; called by muse, mutect2
- KLHL20 | c.222G>A p.V74= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as rs1445512433, COSV52941107; called by muse, mutect2
- KRTAP10-5 | c.33C>T p.S11= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as rs139901000, COSV59972160; called by muse, mutect2
- MXD1 | c.390G>A p.K130= | Silent (SNP) | VAF 23/154 reads (15%) | catalogued as COSV52479435, COSV52480777; called by muse, mutect2, varscan2
- RASGRP4 | c.1425C>T p.F475= | Silent (SNP) | VAF 10/113 reads (9%) | catalogued as rs1384492030, COSV53038510; called by muse, mutect2
- SCEL | c.939G>A p.P313= (on ENST00000349847 / NM_144777.3; = p.P293= on NM_003843.4) | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs1188645237, COSV62993090, COSV62994424; called by muse, mutect2, varscan2
- SEMA5B | c.1164C>T p.C388= | Silent (SNP) | VAF 40/157 reads (25%) | catalogued as rs762915904, COSV52094411; called by muse, mutect2, varscan2
- SLC4A7 | c.1017C>T p.A339= | Silent (SNP) | VAF 28/198 reads (14%) | catalogued as COSV55395958; called by muse, mutect2, varscan2
- SLF2 | c.876G>A p.Q292= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV53272134; called by muse, mutect2, varscan2
- UNC79 | c.7785G>A p.P2595= (on ENST00000393151 / NM_001346218.2; = p.P2418= on NM_020818.5) | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as rs778635073, COSV56381050; called by muse, mutect2
- VAMP7 | c.285G>A p.Q95= | Silent (SNP) | VAF 18/192 reads (9%) | catalogued as COSV52901455; called by muse, mutect2
- ZNF585A | c.1935C>T p.G645= (on ENST00000292841 / NM_001288800.2; = p.G590= on NM_152655.3) | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV53062452; called by muse, mutect2, varscan2
- GH2 | c.457-10C>T | Intron (SNP) | VAF 6/114 reads (5%) | catalogued as COSV100237011; called by muse, mutect2
